Somatic mutation profile of tumor specimen TCGA-HF-7133-01A (aliquot TCGA-HF-7133-01A-11D-2053-08) from TCGA case TCGA-HF-7133, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2.
Specimen TCGA-HF-7133-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2e5f34a-b9ab-49ed-a4c5-9e20d7924944.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HF-7133-10A (Blood Derived Normal), aliquot TCGA-HF-7133-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/712a247b-689e-489c-a9c6-ebf6fc95c9b2

The open-access MAF lists 81 somatic variants for this specimen: 63 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 16, Nonsense Mutation 4, Frame Shift Del 3, RNA 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP11B1 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 78/280 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1326688256, CM960468, COSV52830433, COSV99455840; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.1342C>T p.L448F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53988342; called by muse, mutect2, varscan2
- ADAMTS17 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs540647222, COSV51495472; called by muse, mutect2, varscan2
- ALPG | c.1549C>A p.P517T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54968510; called by mutect2, varscan2
- ALPI | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55016396; called by muse, mutect2, varscan2
- ANKRD13B | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs370819588; called by muse, mutect2, varscan2
- AP3B2 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV55615326; called by muse, mutect2, varscan2
- ARHGAP22 | c.1953G>A p.M651I | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV50997435; called by muse, mutect2, varscan2
- ARHGEF19 | c.1865T>G p.L622R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54618997; called by muse, mutect2, varscan2
- BAG6 | c.821T>C p.L274P | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52995863; called by muse, mutect2, varscan2
- BPIFB4 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs747659473, COSV64951804; called by muse, varscan2
- CLSTN3 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 76/341 reads (22%) | catalogued as rs1330141171, COSV56939572, COSV56940887; called by muse, mutect2, varscan2
- CLTC | c.2115C>G p.F705L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52253768; called by muse, mutect2, varscan2
- COL11A1 | c.2605G>T p.A869S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.097); catalogued as COSV62200163; called by muse, varscan2
- CPNE6 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV53747096; called by muse, mutect2, varscan2
- DEPDC1B | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs141738735; called by muse, mutect2, varscan2
- DHX32 | c.2143G>A p.D715N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs531809485, COSV52943848; called by muse, mutect2, varscan2
- DST | c.15965A>C p.N5322T (on ENST00000361203 / NM_001374722.1; = p.N2910T on NM_015548.5) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV55044115; called by muse, mutect2, varscan2
- DUSP26 | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56362657; called by muse, mutect2, varscan2
- FER1L6 | c.1007T>G p.L336R | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101205892; called by muse, mutect2, varscan2
- FLG | c.9668G>T p.G3223V | Missense Mutation (SNP) | VAF 123/610 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1228150785, COSV64251091; called by muse, mutect2, varscan2
- GAL3ST4 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 78/315 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753576740, COSV57588002; called by muse, mutect2, varscan2
- GIMAP8 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as rs1023463864, COSV56232837; called by muse, mutect2, varscan2
- GLYR1 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs777284077, COSV58929655; called by muse, mutect2, varscan2
- GRM1 | c.3148G>A p.A1050T | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV51121869; called by muse, mutect2
- HERC2 | c.6428C>T p.A2143V | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); catalogued as rs1394393689, COSV55330275, COSV55353074; called by muse, mutect2, varscan2
- HPS4 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61106169; called by muse, mutect2, varscan2
- HSD11B1 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54830353; called by muse, mutect2, varscan2
- ICA1L | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64175529; called by muse, mutect2, varscan2
- INO80C | c.98G>A p.S33N | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as COSV52035012; called by muse, mutect2, varscan2
- INPP5A | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV61253851; called by muse, mutect2
- ITGA4 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52004849; called by muse, mutect2, varscan2
- KCNT1 | c.2731A>G p.M911V (on ENST00000488444; = p.M930V on NM_020822.3) | Missense Mutation (SNP) | VAF 38/367 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as COSV53712317; called by muse, mutect2, varscan2
- KIDINS220 | c.3904G>A p.G1302S | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs538261513, COSV56760061, COSV99875155; called by muse, mutect2, varscan2
- KLRC3 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as rs768046359, COSV101122914, COSV67251385; called by muse, mutect2, varscan2
- KMT5B | c.1442A>G p.K481R | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.891); catalogued as COSV58570108; called by muse, mutect2, varscan2
- KMT5B | c.1277del p.S426Yfs*4 | Frame Shift Del (DEL) | VAF 45/128 reads (35%) | catalogued as COSV58566383; called by mutect2, pindel, varscan2
- LRP11 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs766128487, COSV53335720; called by muse, mutect2, varscan2
- LRRTM1 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs770006134, COSV54443862; called by muse, mutect2, varscan2
- MAP1B | c.6610C>T p.P2204S | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV57107418; called by muse, mutect2, varscan2
- NES | c.3352G>C p.E1118Q | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV63963156; called by muse, mutect2, varscan2
- NTNG1 | c.38G>A p.W13* | Nonsense Mutation (SNP) | VAF 34/123 reads (28%) | catalogued as COSV53990970; called by muse, mutect2, varscan2
- NYAP1 | c.1463C>T p.T488M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs772312233, COSV55718614; called by muse, mutect2, varscan2
- OR4A15 | c.236T>A p.M79K | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV59038149; called by muse, mutect2, varscan2
- OR52B4 | c.351G>T p.L117F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761017611, COSV68769583; called by muse, mutect2, varscan2
- PCDHB8 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 23/364 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs17844484, COSV50765193, COSV50783605; called by muse, mutect2
- PCDHB9 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 96/324 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV53381048; called by muse, mutect2, varscan2
- PDZD2 | c.4477G>A p.A1493T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs745438758, COSV56874887; called by muse, mutect2, varscan2
- PPP2R2B | c.800A>G p.E267G (on ENST00000394409; = p.E333G on NM_181674.2) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV60781930; called by muse, mutect2, varscan2
- PXDN | c.3776C>T p.P1259L | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs369587687, COSV99070649; called by muse, mutect2, varscan2
- R3HDML | c.722G>A p.C241Y | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53837963; called by muse, mutect2, varscan2
- RBM5 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1218891492, COSV61739236; called by muse, mutect2, varscan2
- RSPO2 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV52656201, COSV52657212; called by muse, mutect2, varscan2
- SDK1 | c.2614C>T p.P872S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV67390816; called by muse, mutect2, varscan2
- SLC2A5 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66238249; called by muse, mutect2, varscan2
- SMC5 | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV63195890; called by muse, mutect2, varscan2
- USP51 | c.2078T>A p.L693* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV72352027; called by muse, mutect2, varscan2
- ZNF648 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV60572781; called by muse, mutect2, varscan2
- ZNF768 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV53225036; called by muse, mutect2, varscan2
- ATP1B1 | c.383-2_384del p.X128_splice | Splice Site (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- CHRNA7 | c.1177G>T p.D393Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); called by mutect2, varscan2
- PYGL | c.2229del p.I743Mfs*46 | Frame Shift Del (DEL) | VAF 18/106 reads (17%) | called by mutect2, pindel, varscan2
- ZNF394 | c.842_843del p.S281* | Frame Shift Del (DEL) | VAF 42/186 reads (23%) | called by pindel, varscan2
- BRD1 | c.1335G>A p.P445= | Silent (SNP) | VAF 62/179 reads (35%) | catalogued as rs758434485, COSV53455383, COSV53456487; called by muse, mutect2, varscan2
- CSMD2 | c.4113G>A p.Q1371= | Silent (SNP) | VAF 57/253 reads (23%) | catalogued as COSV53970197; called by muse, mutect2, varscan2
- CSRP2 | c.309T>C p.N103= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV60703684; called by muse, mutect2, varscan2
- DOCK2 | c.3255C>T p.I1085= | Silent (SNP) | VAF 79/256 reads (31%) | catalogued as COSV56992202; called by muse, mutect2, varscan2
- FLG | c.10002G>T p.G3334= | Silent (SNP) | VAF 254/1372 reads (19%) | catalogued as rs775583931, COSV64241302, COSV64251084; called by muse, mutect2
- GRIK5 | c.1365C>T p.A455= | Silent (SNP) | VAF 31/166 reads (19%) | catalogued as rs757152676, COSV53486916; called by muse, mutect2, varscan2
- H2AC8 | c.303G>C p.V101= | Silent (SNP) | VAF 51/217 reads (24%) | catalogued as COSV55127236, COSV55128019; called by muse, mutect2, varscan2
- HAL | c.567C>T p.N189= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV54120648; called by muse, mutect2, varscan2
- KCNQ3 | c.255C>T p.I85= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV66483379; called by muse, mutect2, varscan2
- KCTD6 | c.417C>T p.I139= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV57151298; called by muse, mutect2, varscan2
- MINDY1 | c.390C>T p.T130= | Silent (SNP) | VAF 106/253 reads (42%) | catalogued as rs1285647609, COSV56501318; called by muse, mutect2, varscan2
- MUC5AC | c.1338C>T p.D446= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as rs775592062, COSV62255698; called by muse, mutect2, varscan2
- NELL1 | c.1404T>C p.R468= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV54333196; called by muse, mutect2, varscan2
- PCDHB7 | c.2133G>T p.L711= | Silent (SNP) | VAF 108/1362 reads (8%) | catalogued as COSV50825968; called by muse, mutect2
- TUBB4A | c.981C>T p.D327= | Silent (SNP) | VAF 246/415 reads (59%) | catalogued as rs780784525, COSV51152722; called by muse, mutect2, varscan2
- ZNF318 | c.6609G>A p.L2203= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV58938371; called by muse, mutect2, varscan2
- MIR323A | n.29C>T | RNA (SNP) | VAF 41/173 reads (24%) | catalogued as rs770769777; called by muse, mutect2, varscan2
- ZNF658B | n.2170A>C | RNA (SNP) | VAF 71/266 reads (27%) | called by muse, mutect2, varscan2
